Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3308, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3308-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED] Location: [REDACTED]
DOB: [REDACTED] Service: Medicine
Gender: [REDACTED] Billing #: [REDACTED]
Physician(s): [REDACTED]

Accession #: [REDACTED]
Billing Type: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

Specimen(s) Received

Right kidney

Pathologic Diagnosis

Right kidney:

Histologic Type:	Clear cell (conventional) renal carcinoma
Fuhrman Grade:	2
Tumor Size:	Greatest dimension: 5 cm
Extent of Invasion:	Tumor limited to the kidney and does not involve the renal vein or extend beyond the capsule.
Margins:	Renal vein margin uninvolved by carcinoma Renal artery margin uninvolved by carcinoma Ureter margin uninvolved by carcinoma Lymphovascular invasion absent Venous invasion present
Distant Metastasis:	Cannot be assessed
Specimen Type:	Radical nephrectomy
Adrenal Gland:	Not present

Comment: Carcinoma extends into muscular segmental branches of the renal vein although not into the renal vein.

PATHOLOGIC STAGE: pT3b, pNX, pMX.

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated and does not incorporate other relevant data. Pathology stage is only a component to be considered in determining the clinical stage and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

[page 2 of 2]
Clinical History

Right renal mass.

Gross Description

Received in formalin and labeled "right kidney" is a kidney surfaced by a moderate amount of perirenal fat which together total 399 gm. Trimmed of fat the kidney is 133 gm, 9.3 x 5.8 x 3.8 cm. Arising from the renal pelvis is a 7.8 cm in length and 0.6 cm in diameter segment of ureter, a 2.2 cm in length and 1 cm in diameter segment of renal artery, and a 1.2 cm in length and 0.8 cm in diameter segment of renal vein. No lymph nodes are identified in the renal pelvis and no adrenal gland tissue is identified within the perirenal fat. The kidney is purple-brown with a faint lobulated appearance. On the inferior pole there is a 3.5 cm in diameter spherical nodule with a yellow-tan coloration. In this area the capsule is inked black. The cut surface identifies a 5.5 x 3.5 x 3.5 cm mottled yellow-tan tumor mass with focal areas of hemorrhagic necrosis and white fibrous areas up to 1.2 cm in maximum diameter. In addition, there are cystic structures from 0.1 to 1 cm in diameter. Grossly, the tumor mass extends to the renal capsule but does not penetrate the capsule. In addition, the tumor extends into the vein of the renal pelvis. The remaining renal parenchyma is red-brown. The surface of the cortex exhibits broad-based scars up to 1.6 cm in diameter. In addition, there are renal retention cysts from 0.2 to 0.8 cm. The renal cortex averages 0.5 cm in thickness and the medulla averages 1.2 cm. No other masses or indurated areas are grossly identified. Summary of sections: 1 - surgical margins of the ureter, renal artery and renal vein, 2-4 - tumor mass and renal capsule, 5-6 - tumor mass and renal pelvis, 7 - representative section of renal parenchyma with scar, 8 - representative section of renal parenchyma with renal retention cysts, 9-11 tumor within segmental branches of renal vein.

Microscopic Description

Microscopic examination has been performed on all slides. The pathologic diagnosis encompasses the essential microscopic findings of this case.

Source: NCI Genomic Data Commons file a52157a2-a3d9-40ad-9d40-7479f6950fd3 (TCGA-A3-3308.DE8EB09E-BEC5-4967-8FD1-AF56104AFD2F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).